Somatic mutation profile of cancer-model specimen HCM-CSHL-0586-C32-85D (3D Organoid, passage 4; aliquot HCM-CSHL-0586-C32-85D-01D-A881-36), derived from the primary tumor of HCMI case HCM-CSHL-0586-C32, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0586-C32-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b09a7602-a89f-4eef-b5e4-54f871ade90b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0586-C32-10A (Blood Derived Normal), aliquot HCM-CSHL-0586-C32-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6cfe6b9-f8e1-4627-9daa-270fc176460f

The open-access MAF lists 326 somatic variants for this specimen: 245 protein-altering or splice-affecting, 68 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 68, Nonsense Mutation 15, Intron 7, Splice Site 5, Frame Shift Del 4, 3'Flank 2, Splice Region 2, 3'UTR 2, 5'UTR 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 203/324 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 577/578 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4119+1G>C p.X1373_splice | Splice Site (SNP) | VAF 161/203 reads (79%) | catalogued as CS131684; called by muse, mutect2, varscan2
- ABI3BP | c.2709G>C p.Q903H | Missense Mutation (SNP) | VAF 82/530 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs1378891053; called by muse, mutect2, varscan2
- AFDN | c.4529G>C p.S1510T | Missense Mutation (SNP) | VAF 263/452 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV60053663; called by muse, mutect2, varscan2
- AK9 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 120/233 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs762842091; called by muse, mutect2, varscan2
- ALDOC | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 150/481 reads (31%) | catalogued as rs867498954, COSV52024219; called by muse, mutect2, varscan2
- ANKRD31 | c.5594G>C p.C1865S | Missense Mutation (SNP) | VAF 82/357 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1406560820; called by muse, mutect2, varscan2
- AQR | c.2825C>G p.S942C | Missense Mutation (SNP) | VAF 132/255 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs778172785; called by muse, mutect2, varscan2
- ASAP2 | c.12G>C p.Q4H | Missense Mutation (SNP) | VAF 121/256 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs928852938; called by muse, mutect2, varscan2
- ASPM | c.8379G>A p.M2793I | Missense Mutation (SNP) | VAF 232/467 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs376057172; called by muse, mutect2, varscan2
- B3GNT2 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 213/425 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771301412, COSV100114040; called by muse, mutect2, varscan2
- CAPS2 | c.989G>C p.R330P | Missense Mutation (SNP) | VAF 133/333 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60823981; called by muse, mutect2, varscan2
- CCDC40 | c.1455C>G p.I485M | Missense Mutation (SNP) | VAF 175/177 reads (99%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); catalogued as COSV53897288; called by muse, mutect2, varscan2
- CERT1 | c.1876G>T p.V626L (on ENST00000405807 / NM_001130105.1; = p.V498L on NM_005713.3) | Missense Mutation (SNP) | VAF 166/302 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs779820104, COSV54658074; called by muse, mutect2, varscan2
- CES1 | c.1108G>A p.E370K (on ENST00000361503 / NM_001025194.2; = p.E369K on NM_001266.5) | Missense Mutation (SNP) | VAF 168/597 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); catalogued as rs185780477, COSV100828576; called by muse, mutect2, varscan2
- CHPF | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 212/656 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV60533299; called by muse, mutect2, varscan2
- CHRM4 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 83/415 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1247534212, COSV63127569; called by muse, mutect2, varscan2
- CLSTN2 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as rs1279936593; called by muse, mutect2, varscan2
- CLSTN2 | c.2710G>C p.E904Q | Missense Mutation (SNP) | VAF 172/558 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV71719844; called by muse, varscan2
- COL24A1 | c.2078G>T p.G693V | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976118816; called by muse, mutect2, varscan2
- COL25A1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 387/693 reads (56%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV67651309; called by muse, mutect2, varscan2
- CPLANE1 | c.134G>C p.R45T (on ENST00000425232; = p.R117T on NM_023073.3) | Missense Mutation (SNP) | VAF 146/406 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs1324311439; called by muse, mutect2, varscan2
- CRACD | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 341/628 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.073); catalogued as rs568276295, COSV51715441; called by muse, mutect2, varscan2
- CSNKA2IP | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1442002055; called by muse, mutect2, varscan2
- EPS8L1 | c.1901C>G p.S634W (on ENST00000201647 / NM_133180.3; = p.S507W on NM_017729.3) | Missense Mutation (SNP) | VAF 229/722 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777409786; called by muse, mutect2, varscan2
- FAT4 | c.10367C>G p.S3456C | Missense Mutation (SNP) | VAF 156/304 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58696413; called by muse, mutect2, varscan2
- FBXL13 | c.1530G>C p.L510F | Missense Mutation (SNP) | VAF 129/239 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756557162; called by muse, mutect2, varscan2
- FCAR | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 356/583 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as rs372465584, COSV62030495; called by muse, mutect2, varscan2
- FMN2 | c.3097C>G p.P1033A | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV60434495; called by muse, varscan2
- GALNT14 | c.1036G>C p.G346R | Missense Mutation (SNP) | VAF 112/419 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61109578; called by muse, mutect2, varscan2
- GMEB2 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 401/769 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs752805008, COSV56607678; called by muse, mutect2, varscan2
- GNE | c.1352G>A p.R451Q (on ENST00000396594 / NM_001128227.3; = p.R420Q on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/291 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs780092539, COSV64951478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN3A | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 132/525 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs758777062; called by muse, mutect2, varscan2
- H2AZ2 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 275/824 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV56062069; called by muse, mutect2, varscan2
- H2BW2 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 369/370 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs373863467; called by muse, mutect2, varscan2
- H4C11 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.954); catalogued as rs758581420, COSV100747976; called by muse, mutect2, varscan2
- HEATR5A | c.5491G>A p.E1831K | Missense Mutation (SNP) | VAF 298/302 reads (99%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as COSV101119736; called by muse, mutect2, varscan2
- HFM1 | c.1969C>G p.R657G | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443376631; called by muse, mutect2, varscan2
- JADE2 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 303/534 reads (57%) | catalogued as COSV50927131; called by muse, mutect2, varscan2
- KCNC3 | c.1874G>C p.R625T | Missense Mutation (SNP) | VAF 474/699 reads (68%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs913429586, COSV65387207; called by muse, mutect2, varscan2
- KCNQ4 | c.2035G>A p.V679I | Missense Mutation (SNP) | VAF 357/728 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV61275555; called by muse, mutect2, varscan2
- KCTD16 | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 351/623 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72579285; called by muse, mutect2, varscan2
- KIF13B | c.4674del p.S1559Afs*3 | Frame Shift Del (DEL) | VAF 360/885 reads (41%) | catalogued as rs1182415107; called by mutect2, pindel, varscan2
- L3MBTL2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 274/564 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs745928119; called by muse, mutect2, varscan2
- LETM1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 242/418 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs763003148; called by muse, mutect2, varscan2
- LILRA5 | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 90/553 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.449); catalogued as rs749443711; called by muse, mutect2, varscan2
- LRP2 | c.10070C>T p.S3357F | Missense Mutation (SNP) | VAF 112/351 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV55574533; called by muse, mutect2, varscan2
- LY75-CD302 | c.5515G>C p.D1839H | Missense Mutation (SNP) | VAF 188/299 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs747473972; called by muse, varscan2
- MAFF | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 238/498 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV58299548; called by muse, mutect2, varscan2
- MAGEL2 | c.3235G>C p.E1079Q | Missense Mutation (SNP) | VAF 236/496 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV58566195; called by muse, mutect2, varscan2
- MASP1 | c.963C>G p.F321L | Missense Mutation (SNP) | VAF 188/564 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.198); catalogued as COSV51460744, COSV99397544; called by muse, mutect2, varscan2
- MEX3B | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 372/722 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as rs538400491, COSV100313919; called by muse, mutect2, varscan2
- MORC1 | c.1596C>G p.I532M | Missense Mutation (SNP) | VAF 116/474 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV51730272; called by muse, mutect2, varscan2
- MROH2B | c.4675C>G p.P1559A | Missense Mutation (SNP) | VAF 87/414 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV68182763; called by muse, mutect2, varscan2
- MTMR11 | c.1303C>G p.L435V (on ENST00000439741 / NM_001145862.2; = p.L363V on NM_181873.3) | Missense Mutation (SNP) | VAF 85/347 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV54965491; called by muse, mutect2, varscan2
- MYNN | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 190/579 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747581519; called by muse, mutect2, varscan2
- MYO6 | c.1737C>G p.I579M | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs763342831; called by muse, mutect2, varscan2
- NAA25 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 168/342 reads (49%) | catalogued as rs1287477535, COSV55709487; called by muse, mutect2, varscan2
- NOTCH3 | c.404C>A p.S135* | Nonsense Mutation (SNP) | VAF 368/816 reads (45%) | catalogued as rs1356781250; called by muse, mutect2, varscan2
- NPR3 | c.393C>G p.I131M | Missense Mutation (SNP) | VAF 326/1159 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV54092987; called by muse, mutect2, varscan2
- NR3C2 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 103/291 reads (35%) | catalogued as rs1320684797; called by muse, mutect2, varscan2
- NRTN | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 391/393 reads (99%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as rs1292681887; called by muse, mutect2, varscan2
- OBSCN | c.12116G>C p.G4039A | Missense Mutation (SNP) | VAF 290/655 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV52735651; called by muse, mutect2, varscan2
- OR4S2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 97/389 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV56748245; called by muse, mutect2, varscan2
- OXR1 | c.327G>C p.L109F (on ENST00000442977 / NM_001198532.1; = p.L108F on NM_018002.3) | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56326708; called by muse, mutect2, varscan2
- PALLD | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 109/258 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs772476893, COSV54984881; called by muse, mutect2, varscan2
- PAPSS2 | c.1200G>C p.M400I | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100753730; called by muse, mutect2, varscan2
- PARP12 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 175/408 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54934039; called by muse, mutect2, varscan2
- PCDH7 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 360/664 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62337676; called by muse, mutect2, varscan2
- PGAP4 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 244/545 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66387982; called by muse, mutect2, varscan2
- PGPEP1L | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 384/814 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs766570886; called by muse, mutect2, varscan2
- PHKB | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 125/264 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs373243537, COSV54524124; called by muse, mutect2, varscan2
- PLCH1 | c.3826G>T p.E1276* (on ENST00000340059 / NM_001130960.2; = p.E1268* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 225/642 reads (35%) | catalogued as COSV58207497; called by muse, mutect2, varscan2
- PLEKHH1 | c.3323G>A p.R1108Q | Missense Mutation (SNP) | VAF 323/330 reads (98%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs1006856087; called by muse, mutect2, varscan2
- PLEKHO2 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 281/648 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60261708; called by muse, mutect2, varscan2
- PPP1R37 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 318/492 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.224); catalogued as rs1489093950; called by muse, mutect2
- PPP1R7 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 134/202 reads (66%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs1299392369, COSV52145717; called by muse, mutect2, varscan2
- PRDM7 | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 174/361 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV104434984; called by muse, mutect2, varscan2
- PTMA | c.190G>C p.E64Q (on ENST00000341369 / NM_001099285.2; = p.E63Q on NM_002823.5) | Missense Mutation (SNP) | VAF 141/246 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV58187895; called by muse, mutect2, varscan2
- RBL1 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 197/442 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as COSV60331503; called by muse, mutect2, varscan2
- RDX | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 207/208 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as COSV58193025; called by muse, mutect2, varscan2
- REM1 | c.708C>G p.F236L | Missense Mutation (SNP) | VAF 433/917 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as COSV52427894; called by muse, mutect2, varscan2
- RNF167 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 333/734 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99337254; called by muse, mutect2, varscan2
- RPL8 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 280/695 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs778652220, COSV52799438; called by muse, mutect2, varscan2
- RUSC1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 334/701 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV52741346; called by muse, mutect2, varscan2
- SBNO2 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 288/289 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as rs771453105; called by muse, mutect2, varscan2
- SBNO2 | c.1353C>G p.F451L | Missense Mutation (SNP) | VAF 261/263 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62323482; called by muse, mutect2, varscan2
- SCAI | c.706G>C p.E236Q (on ENST00000336505 / NM_001144877.3; = p.E259Q on NM_173690.5) | Missense Mutation (SNP) | VAF 139/322 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV100332774; called by muse, mutect2, varscan2
- SGO1 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 134/275 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs201455258; called by muse, mutect2, varscan2
- SHISA6 | c.1141G>A p.E381K (on ENST00000409168 / NM_001173461.1; = p.E432K on NM_207386.4) | Missense Mutation (SNP) | VAF 295/636 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as rs1413780172; called by muse, mutect2, varscan2
- SLC35G2 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 92/339 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101262014; called by muse, mutect2, varscan2
- SLC44A5 | c.1480G>C p.D494H | Missense Mutation (SNP) | VAF 194/401 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV63769674; called by muse, mutect2, varscan2
- SLC9A3R1 | c.444C>T p.R148= | Splice Region (SNP) | VAF 84/1206 reads (7%) | catalogued as rs146791449, COSV99379862; called by muse, mutect2
- SMG1 | c.9629A>G p.N3210S | Missense Mutation (SNP) | VAF 171/362 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1403195291; called by muse, mutect2, varscan2
- STARD9 | c.7011G>C p.L2337F | Missense Mutation (SNP) | VAF 249/508 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as rs1279058394; called by muse, mutect2, varscan2
- SYMPK | c.2704G>C p.E902Q | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV99842234; called by muse, mutect2, varscan2
- TUBD1 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 471/591 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs774443751; called by muse, mutect2, varscan2
- USF3 | c.1984C>G p.Q662E | Missense Mutation (SNP) | VAF 182/699 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs763985151, COSV57076619; called by muse, mutect2, varscan2
- WDR33 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 168/275 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs770304067, COSV100460372; called by muse, mutect2, varscan2
- ZBTB45 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 120/346 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs778329030, COSV54021032; called by muse, mutect2, varscan2
- ZNF503 | c.579_587del p.G202_G204del | In Frame Del (DEL) | VAF 211/518 reads (41%) | catalogued as rs1044655354; called by mutect2, varscan2
- ZNF652 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 102/381 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV100755635; called by muse, mutect2, varscan2
- ZNF697 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 400/806 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101360129; called by muse, mutect2, varscan2
- ABCG8 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 227/471 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); called by muse, mutect2
- ACAN | c.71-1G>C p.X24_splice | Splice Site (SNP) | VAF 204/398 reads (51%) | called by muse, varscan2
- ACSL6 | c.1336C>T p.L446F (on ENST00000379240; = p.L471F on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 200/366 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.309); called by muse, varscan2
- ADAMTS6 | c.420A>C p.Q140H | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- AJUBA | c.576_589del p.A193Rfs*108 | Frame Shift Del (DEL) | VAF 747/792 reads (94%) | called by mutect2, pindel, varscan2
- AKAP6 | c.5649C>G p.F1883L | Missense Mutation (SNP) | VAF 61/302 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AMBRA1 | c.1106C>T p.S369F (on ENST00000458649 / NM_001367468.1; = p.S279F on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 212/324 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); called by mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 203/534 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ANKRD17 | c.1188T>A p.H396Q | Missense Mutation (SNP) | VAF 132/325 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ANXA11 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 264/567 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ARHGEF9 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 179/181 reads (99%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.790C>A p.H264N | Missense Mutation (SNP) | VAF 171/171 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP1A4 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 95/434 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP5PD | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 168/1556 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BFAR | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 184/385 reads (48%) | called by muse, mutect2, varscan2
- BTBD7 | c.2323C>G p.Q775E | Missense Mutation (SNP) | VAF 234/512 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BUB1 | c.2857A>G p.M953V | Missense Mutation (SNP) | VAF 231/371 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- BUB1 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 220/359 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C16orf91 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 302/664 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- C8orf48 | c.805A>T p.S269C | Missense Mutation (SNP) | VAF 164/358 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CAPRIN2 | c.2735C>G p.S912C | Missense Mutation (SNP) | VAF 233/471 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CATSPERE | c.1201C>G p.L401V | Missense Mutation (SNP) | VAF 210/417 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CBFA2T2 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 210/451 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDC42BPG | c.1279G>T p.V427L | Missense Mutation (SNP) | VAF 122/617 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFHR2 | c.179T>G p.V60G | Missense Mutation (SNP) | VAF 169/363 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CLIC3 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 312/616 reads (51%) | called by muse, mutect2, varscan2
- CLUL1 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 215/938 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNOT1 | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 202/389 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CUX1 | c.4097_4134del p.V1366Gfs*172 | Frame Shift Del (DEL) | VAF 191/616 reads (31%) | called by mutect2, pindel, varscan2
- CYC1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 232/541 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CYP2R1 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 225/305 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DAPK1 | c.857G>C p.R286T | Missense Mutation (SNP) | VAF 141/302 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDAH1 | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 166/320 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DDIT3 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 307/612 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DGKK | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 363/364 reads (100%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DHCR24 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 248/525 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DMD | c.9391G>C p.D3131H | Missense Mutation (SNP) | VAF 239/240 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- DNAH7 | c.5101G>C p.E1701Q | Missense Mutation (SNP) | VAF 206/353 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSTYK | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 199/395 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTL | c.1445G>T p.R482I | Missense Mutation (SNP) | VAF 233/493 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEA1 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 145/299 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- EMILIN2 | c.2111G>T p.G704V | Missense Mutation (SNP) | VAF 194/780 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- ETNPPL | c.1068G>C p.L356F | Missense Mutation (SNP) | VAF 104/240 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FER | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 129/260 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GATA5 | c.368G>C p.R123P | Missense Mutation (SNP) | VAF 608/1158 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GATA5 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 496/1051 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.703); called by muse, mutect2
- GLG1 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 125/279 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GNPAT | c.1523-1G>A p.X508_splice | Splice Site (SNP) | VAF 92/183 reads (50%) | called by muse, mutect2, varscan2
- GRIA1 | c.2064G>A p.M688I | Missense Mutation (SNP) | VAF 240/406 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GRIN3A | c.1636C>A p.P546T | Missense Mutation (SNP) | VAF 131/518 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- GSDMA | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 248/389 reads (64%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HDAC4 | c.1776+1G>T p.X592_splice | Splice Site (SNP) | VAF 227/369 reads (62%) | called by muse, mutect2, varscan2
- HDAC4 | c.1776G>A p.Q592= | Splice Region (SNP) | VAF 228/373 reads (61%) | called by muse, mutect2, varscan2
- HECW2 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 247/404 reads (61%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- HELZ2 | c.7335G>C p.K2445N (on ENST00000467148 / NM_001037335.2; = p.K1876N on NM_033405.3) | Missense Mutation (SNP) | VAF 27/817 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); called by muse, mutect2
- HERPUD1 | c.925C>G p.P309A | Missense Mutation (SNP) | VAF 150/344 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HHAT | c.1040T>C p.I347T | Missense Mutation (SNP) | VAF 127/240 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- HLA-A | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 259/418 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HS3ST1 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 180/399 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ID3 | c.269G>C p.G90A | Missense Mutation (SNP) | VAF 242/539 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV3-27 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 105/230 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- INTS6L | c.2200G>A p.G734S | Missense Mutation (SNP) | VAF 299/301 reads (99%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IQGAP3 | c.4184G>C p.R1395T | Missense Mutation (SNP) | VAF 157/313 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- JAK2 | c.1835A>G p.N612S | Missense Mutation (SNP) | VAF 575/879 reads (65%) | SIFT tolerated (0.24); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- KIAA1210 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 295/295 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- KIF26B | c.3445G>T p.E1149* | Nonsense Mutation (SNP) | VAF 325/702 reads (46%) | called by muse, mutect2, varscan2
- KLHL10 | c.637C>G p.H213D | Missense Mutation (SNP) | VAF 83/295 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- KLHL25 | c.1422C>G p.I474M | Missense Mutation (SNP) | VAF 306/652 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- LMTK2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 178/334 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC8A | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 284/601 reads (47%) | called by muse, mutect2, varscan2
- MAP3K13 | c.2662C>G p.L888V | Missense Mutation (SNP) | VAF 102/854 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MEF2D | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 233/436 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MMP24 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 110/204 reads (54%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); called by muse, varscan2
- MTERF1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 211/425 reads (50%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MTO1 | c.1432G>A p.D478N (on ENST00000370300 / NM_133645.3; = p.D453N on NM_012123.4) | Missense Mutation (SNP) | VAF 226/413 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NBR1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 168/561 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NCBP2AS2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 351/1012 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- NDUFB3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 174/279 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NFIL3 | c.162G>C p.K54N | Missense Mutation (SNP) | VAF 217/507 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- NFKB2 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 169/558 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NFKBIZ | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 146/494 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- NOTCH1 | c.6001C>G p.L2001V | Missense Mutation (SNP) | VAF 385/743 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP88 | c.1058G>C p.W353S | Missense Mutation (SNP) | VAF 162/338 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NWD1 | c.1984G>C p.E662Q | Missense Mutation (SNP) | VAF 190/303 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.055); called by muse, mutect2
- OR14A2 | c.737_748delinsCACTGTT p.F246Sfs*12 | Frame Shift Del (DEL) | VAF 138/323 reads (43%) | called by pindel, varscan2*
- OR7G2 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PARM1 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 216/477 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PDE3B | c.31A>G p.M11V | Missense Mutation (SNP) | VAF 339/459 reads (74%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PIEZO2 | c.2269G>C p.E757Q | Missense Mutation (SNP) | VAF 116/609 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- PIK3CB | c.1909C>G p.Q637E | Missense Mutation (SNP) | VAF 110/376 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PKD1L1 | c.6822G>A p.M2274I | Missense Mutation (SNP) | VAF 249/750 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCE1 | c.4355A>G p.H1452R | Missense Mutation (SNP) | VAF 118/184 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PPP1CA | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 278/694 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4R4 | c.2533A>G p.T845A | Missense Mutation (SNP) | VAF 502/506 reads (99%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRT1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 102/368 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRUNE2 | c.4252G>A p.G1418R | Missense Mutation (SNP) | VAF 248/534 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PZP | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 195/418 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RFC1 | c.509G>C p.G170A | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RFX7 | c.2904G>A p.M968I (on ENST00000559447 / NM_001368074.1; = p.M1065I on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 235/467 reads (50%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RNF168 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 217/601 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- RPLP0 | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 291/624 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SBNO2 | c.1152C>G p.I384M | Missense Mutation (SNP) | VAF 226/226 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SBNO2 | c.918C>G p.F306L | Missense Mutation (SNP) | VAF 281/281 reads (100%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SERPINB9 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 150/431 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SGIP1 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 295/627 reads (47%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A5 | c.2338C>G p.L780V (on ENST00000454036 / NM_001134771.2; = p.L757V on NM_020708.5) | Missense Mutation (SNP) | VAF 371/698 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SLC16A5 | c.1218C>G p.I406M | Missense Mutation (SNP) | VAF 126/2092 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2
- SLC38A6 | c.1412G>C p.R471T | Missense Mutation (SNP) | VAF 240/241 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); called by muse, varscan2
- SLC38A6 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 293/293 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by muse, varscan2
- SLC4A10 | c.1618-1G>A p.X540_splice (on ENST00000446997 / NM_001354461.2; = p.X510_splice on NM_022058.4 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 91/248 reads (37%) | called by muse, mutect2, varscan2
- SLC6A18 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 390/558 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- SLC9A3R1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 352/2095 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SOX3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 301/301 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SPIRE2 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 230/452 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- SRFBP1 | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 188/412 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ST13 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 175/349 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TADA2A | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 204/327 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TARBP1 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 323/675 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TDRD5 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 238/480 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TIGD7 | c.1584G>C p.L528F | Missense Mutation (SNP) | VAF 168/354 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM88 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 299/615 reads (49%) | called by muse, mutect2, varscan2
- TOPBP1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 108/295 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRAPPC9 | c.1553T>C p.M518T | Missense Mutation (SNP) | VAF 90/446 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- TTN | c.54344G>C p.R18115T (on ENST00000591111; = p.R10691T on NM_003319.4) | Missense Mutation (SNP) | VAF 117/326 reads (36%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ULK4 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 136/348 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USP34 | c.7850C>T p.P2617L | Missense Mutation (SNP) | VAF 81/370 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VANGL2 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 138/271 reads (51%) | called by muse, mutect2, varscan2
- VEPH1 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 177/597 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDCP | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 219/481 reads (46%) | called by muse, mutect2, varscan2
- WDFY3 | c.6620T>C p.L2207P | Missense Mutation (SNP) | VAF 159/302 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WHAMM | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 50/324 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WRNIP1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 304/911 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ZBED9 | c.3717T>G p.S1239R | Missense Mutation (SNP) | VAF 117/363 reads (32%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZC3H11B | c.2171G>C p.R724T | Missense Mutation (SNP) | VAF 207/934 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ZCCHC2 | c.707C>G p.S236* | Nonsense Mutation (SNP) | VAF 471/473 reads (100%) | called by muse, mutect2, varscan2
- ZDHHC8 | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 34/568 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZMYM4 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 126/325 reads (39%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZMYM5 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 147/148 reads (99%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF462 | c.650A>C p.K217T | Missense Mutation (SNP) | VAF 321/602 reads (53%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ZNF750 | c.842_843insTC p.H283Dfs*84 | Frame Shift Ins (INS) | VAF 237/331 reads (72%) | called by mutect2, pindel, varscan2
- ZNF761 | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 146/232 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ABCB4 | c.1095T>C p.Y365= | Silent (SNP) | VAF 112/254 reads (44%) | called by muse, mutect2, varscan2
- ADAP1 | c.981C>T p.I327= | Silent (SNP) | VAF 324/1036 reads (31%) | catalogued as rs371003070; called by muse, mutect2, varscan2
- ADGRG1 | c.1704G>A p.L568= | Silent (SNP) | VAF 205/458 reads (45%) | catalogued as COSV101113398; called by muse, mutect2, varscan2
- ADORA1 | c.264C>G p.L88= | Silent (SNP) | VAF 270/606 reads (45%) | called by muse, mutect2, varscan2
- ANO10 | c.753C>T p.L251= | Silent (SNP) | VAF 194/382 reads (51%) | catalogued as rs753407149; called by muse, mutect2, varscan2
- ATXN2L | c.288C>T p.I96= | Silent (SNP) | VAF 274/572 reads (48%) | called by muse, mutect2, varscan2
- C1QL1 | c.408C>G p.L136= | Silent (SNP) | VAF 154/509 reads (30%) | called by muse, mutect2, varscan2
- CCDC180 | c.3906C>T p.F1302= | Silent (SNP) | VAF 198/420 reads (47%) | called by muse, mutect2, varscan2
- CCNB3 | c.3837G>A p.L1279= | Silent (SNP) | VAF 245/250 reads (98%) | called by muse, mutect2, varscan2
- CDHR4 | c.1317C>T p.N439= | Silent (SNP) | VAF 230/488 reads (47%) | catalogued as rs113873087, COSV58525768; called by muse, mutect2, varscan2
- CEP72 | c.1404G>A p.A468= | Silent (SNP) | VAF 255/798 reads (32%) | catalogued as rs953228337; called by muse, mutect2, varscan2
- CNTROB | c.2676G>A p.P892= | Silent (SNP) | VAF 280/597 reads (47%) | catalogued as rs572722264, COSV100972613, COSV66609146; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2931C>T p.L977= | Silent (SNP) | VAF 336/634 reads (53%) | called by muse, mutect2, varscan2
- CRYGS | c.453C>G p.L151= | Silent (SNP) | VAF 217/677 reads (32%) | called by muse, mutect2, varscan2
- CUL9 | c.4512C>G p.L1504= | Silent (SNP) | VAF 125/405 reads (31%) | catalogued as rs550906648; called by muse, mutect2, varscan2
- CXCR6 | c.771C>T p.H257= | Silent (SNP) | VAF 425/426 reads (100%) | catalogued as rs1447643070; called by muse, mutect2, varscan2
- DBF4B | c.540G>A p.R180= | Silent (SNP) | VAF 102/324 reads (31%) | called by muse, mutect2, varscan2
- DCAKD | c.249C>G p.L83= | Silent (SNP) | VAF 273/412 reads (66%) | called by muse, mutect2, varscan2
- DCHS1 | c.5958G>A p.L1986= | Silent (SNP) | VAF 328/457 reads (72%) | catalogued as COSV55031013; called by muse, mutect2, varscan2
- DNAH17 | c.66C>T p.F22= | Silent (SNP) | VAF 284/285 reads (100%) | called by muse, mutect2, varscan2
- ELMO2 | c.2148C>T p.V716= | Silent (SNP) | VAF 121/258 reads (47%) | called by muse, mutect2
- EYS | c.7548G>A p.L2516= | Silent (SNP) | VAF 151/334 reads (45%) | called by muse, mutect2, varscan2
- FAM189A1 | c.531C>G p.L177= | Silent (SNP) | VAF 240/489 reads (49%) | called by muse, mutect2, varscan2
- FAT4 | c.10173C>T p.V3391= | Silent (SNP) | VAF 123/247 reads (50%) | catalogued as rs1301574952; called by muse, mutect2, varscan2
- FOXF1 | c.717C>T p.H239= | Silent (SNP) | VAF 339/661 reads (51%) | catalogued as COSV99296296; called by muse, mutect2, varscan2
- FSIP2 | c.4080T>C p.C1360= | Silent (SNP) | VAF 82/222 reads (37%) | called by muse, mutect2, varscan2
- GNA12 | c.420G>T p.L140= | Silent (SNP) | VAF 211/793 reads (27%) | catalogued as COSV51746493; called by muse, mutect2, varscan2
- GPR1 | c.702G>A p.K234= | Silent (SNP) | VAF 180/295 reads (61%) | called by muse, mutect2, varscan2
- HDAC9 | c.2277C>T p.I759= | Silent (SNP) | VAF 341/545 reads (63%) | catalogued as rs1060499865, COSV67775548; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEATR3 | c.318C>G p.L106= | Silent (SNP) | VAF 124/274 reads (45%) | catalogued as COSV53530196; called by muse, mutect2, varscan2
- HERC1 | c.13353C>G p.V4451= | Silent (SNP) | VAF 195/431 reads (45%) | called by muse, mutect2, varscan2
- HYOU1 | c.534C>G p.V178= | Silent (SNP) | VAF 239/242 reads (99%) | catalogued as rs1345794690; called by muse, mutect2, varscan2
- INSC | c.1197C>T p.I399= | Silent (SNP) | VAF 87/401 reads (22%) | catalogued as rs1564914013, COSV65410413; called by muse, mutect2, varscan2
- KIFC3 | c.879G>C p.L293= | Silent (SNP) | VAF 300/598 reads (50%) | called by muse, mutect2, varscan2
- KRT81 | c.1422G>A p.L474= | Silent (SNP) | VAF 265/565 reads (47%) | catalogued as rs748777793; called by muse, mutect2, varscan2
- LAMA4 | c.2970C>T p.N990= (on ENST00000230538 / NM_001105206.3; = p.N983= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 101/269 reads (38%) | called by muse, mutect2, varscan2
- MANEA | c.841C>T p.L281= | Silent (SNP) | VAF 136/339 reads (40%) | catalogued as COSV62590011; called by muse, mutect2, varscan2
- MUC12 | c.8181G>A p.S2727= (on ENST00000379442; = p.S2584= on NM_001164462.1) | Silent (SNP) | VAF 210/1142 reads (18%) | called by muse, mutect2, varscan2
- MYO15B | c.9178C>T p.L3060= | Silent (SNP) | VAF 156/2780 reads (6%) | called by muse, mutect2
- NOMO1 | c.2319C>G p.L773= | Silent (SNP) | VAF 70/345 reads (20%) | called by muse, mutect2, varscan2
- NTAQ1 | c.207G>A p.A69= | Silent (SNP) | VAF 149/461 reads (32%) | catalogued as rs374491156; called by muse, mutect2, varscan2
- OR10J4 | c.522C>A p.L174= | Silent (SNP) | VAF 180/386 reads (47%) | called by mutect2, varscan2
- OR2W3 | c.570C>T p.V190= | Silent (SNP) | VAF 214/422 reads (51%) | called by muse, mutect2
- OR9G1 | c.720C>T p.C240= | Silent (SNP) | VAF 122/753 reads (16%) | catalogued as rs896979856; called by muse, mutect2, varscan2
- OTOP3 | c.213C>T p.L71= | Silent (SNP) | VAF 174/2898 reads (6%) | called by muse, mutect2
- PDE8B | c.2571G>A p.L857= | Silent (SNP) | VAF 151/329 reads (46%) | called by muse, mutect2, varscan2
- PHC1 | c.168C>T p.F56= | Silent (SNP) | VAF 179/400 reads (45%) | called by muse, mutect2, varscan2
- PLEC | c.12177C>G p.T4059= (on ENST00000322810 / NM_201380.4; = p.T3949= on NM_000445.5) | Silent (SNP) | VAF 206/510 reads (40%) | called by muse, mutect2, varscan2
- PLEC | c.11496C>G p.V3832= (on ENST00000322810 / NM_201380.4; = p.V3722= on NM_000445.5) | Silent (SNP) | VAF 333/796 reads (42%) | called by muse, mutect2, varscan2
- PLPPR5 | c.144C>T p.S48= | Silent (SNP) | VAF 327/649 reads (50%) | called by muse, mutect2, varscan2
- PLXNB2 | c.5094C>T p.F1698= | Silent (SNP) | VAF 259/571 reads (45%) | catalogued as rs755761136; called by muse, mutect2, varscan2
- POLA1 | c.1626C>T p.F542= | Silent (SNP) | VAF 232/232 reads (100%) | catalogued as COSV66891001; called by muse, mutect2, varscan2
- RPL37 | c.187C>A p.R63= | Silent (SNP) | VAF 200/676 reads (30%) | catalogued as COSV57038084; called by muse, mutect2
- SMAP1 | c.1383C>T p.L461= (on ENST00000370455 / NM_001044305.3; = p.L434= on NM_021940.5) | Silent (SNP) | VAF 193/299 reads (65%) | catalogued as COSV100017377; called by muse, mutect2, varscan2
- SOX30 | c.1897C>A p.R633= (on ENST00000265007 / NM_178424.2; = p.V468= on NM_007017.2) | Silent (SNP) | VAF 91/444 reads (20%) | called by muse, mutect2, varscan2
- SPATA31D3 | c.2388T>G p.S796= | Silent (SNP) | VAF 344/372 reads (92%) | called by muse, mutect2, varscan2
- STIM2 | c.2226G>A p.K742= | Silent (SNP) | VAF 111/206 reads (54%) | called by muse, mutect2, varscan2
- TACC2 | c.2715C>T p.L905= | Silent (SNP) | VAF 127/452 reads (28%) | called by muse, mutect2, varscan2
- TICRR | c.2901C>G p.A967= | Silent (SNP) | VAF 167/339 reads (49%) | catalogued as COSV51541799; called by muse, mutect2, varscan2
- TIE1 | c.3198G>A p.L1066= | Silent (SNP) | VAF 24/540 reads (4%) | called by muse, mutect2
- TM7SF3 | c.297C>T p.F99= | Silent (SNP) | VAF 206/444 reads (46%) | called by muse, mutect2, varscan2
- TMOD2 | c.687G>A p.K229= | Silent (SNP) | VAF 208/412 reads (50%) | called by muse, mutect2, varscan2
- TRIM49 | c.1329C>G p.L443= | Silent (SNP) | VAF 70/229 reads (31%) | called by muse, mutect2, varscan2
- TTC6 | c.150C>T p.I50= (on ENST00000267368; = p.I1319= on NM_001310135.3) | Silent (SNP) | VAF 156/333 reads (47%) | called by muse, mutect2, varscan2
- UBR3 | c.15C>T p.A5= | Silent (SNP) | VAF 139/418 reads (33%) | catalogued as rs1033817353; called by muse, mutect2, varscan2
- UNC80 | c.4887G>A p.L1629= | Silent (SNP) | VAF 222/354 reads (63%) | called by muse, mutect2, varscan2
- ZNF282 | c.1563C>T p.P521= | Silent (SNP) | VAF 329/689 reads (48%) | catalogued as rs141536445, COSV100021389; called by muse, mutect2, varscan2
- ZNF670 | c.888C>T p.L296= | Silent (SNP) | VAF 184/416 reads (44%) | called by muse, mutect2, varscan2
- ARL6IP5 | c.*255G>C | 3'UTR (SNP) | VAF 128/280 reads (46%) | called by muse, mutect2, varscan2
- DOK7 | chr4:3496833 C>T | 3'Flank (SNP) | VAF 227/425 reads (53%) | catalogued as rs760282991; called by muse, mutect2, varscan2
- H2BP2 | chr1:143876197 G>A | 3'Flank (SNP) | VAF 244/1019 reads (24%) | catalogued as rs1479938466; called by muse, mutect2, varscan2
- MRPL20 | c.276+84C>G | Intron (SNP) | VAF 87/693 reads (13%) | called by muse, mutect2, varscan2
- PITX2 | c.185-950G>C | Intron (SNP) | VAF 214/502 reads (43%) | called by muse, mutect2, varscan2
- PSMD6 | c.146-132C>T | Intron (SNP) | VAF 154/332 reads (46%) | catalogued as rs1188762387; called by muse, mutect2, varscan2
- RABL6 | c.-1G>A | 5'UTR (SNP) | VAF 235/457 reads (51%) | called by muse, mutect2, varscan2
- RBBP7 | c.17-346C>G | Intron (SNP) | VAF 328/328 reads (100%) | called by muse, mutect2, varscan2
- SENP3 | c.716-131G>C | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- SLC39A14 | c.457+1541C>T | Intron (SNP) | VAF 241/562 reads (43%) | catalogued as COSV51485585; called by muse, mutect2, varscan2
- SPTLC1 | c.*147G>A | 3'UTR (SNP) | VAF 112/265 reads (42%) | catalogued as rs544879549; called by muse, mutect2, varscan2
- TMEM116 | c.-94C>G | 5'UTR (SNP) | VAF 75/175 reads (43%) | called by muse, mutect2, varscan2
- TTN | c.10360+1775G>C | Intron (SNP) | VAF 127/226 reads (56%) | catalogued as rs1458319550, COSV59950440, COSV60212092; called by muse, mutect2, varscan2
